CPTAC case 01OV013 — Ovary — Cystic, Mucinous and Serous Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/dc8e3901-b845-4419-8f76-d31750eacf60

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Serous adenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 7c01454f-a189-4a70-881f-313126: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample 95c2a5bf-a27b-4c83-8791-160e03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
